Somatic mutation profile of tumor specimen 0DC62X from CCDI case PBBLZZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Large cell medulloblastoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 7.1 years (2,592 days).
Specimen 0DC62X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 232f401b-123b-4d38-9803-ff2782b1c9c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DC635 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/169abbc1-1275-4f1b-ae0a-06d5813453d1

The open-access MAF lists 47 somatic variants for this specimen: 29 protein-altering or splice-affecting, 10 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 10, Intron 4, 5'UTR 2, Nonsense Mutation 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PKLR | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 55/530 reads (10%) | catalogued as rs772567442; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLTC | c.701G>C p.G234A | Missense Mutation (SNP) | VAF 113/312 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.726); catalogued as COSV52246663; called by muse, mutect2, varscan2
- FUT9 | c.623A>T p.E208V | Missense Mutation (SNP) | VAF 146/430 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767637286; called by muse, mutect2, varscan2
- KHDRBS2 | c.440G>C p.R147P | Missense Mutation (SNP) | VAF 45/410 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55434666, COSV99832969; called by muse, mutect2, varscan2
- LAMA3 | c.6563C>T p.A2188V (on ENST00000313654 / NM_198129.4; = p.A579V on NM_000227.6) | Missense Mutation (SNP) | VAF 108/351 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs145422538; called by muse, mutect2, varscan2
- LILRB2 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 72/267 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs771068803; called by muse, mutect2, varscan2
- NLRP5 | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 91/314 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.731); catalogued as rs199475775, COSV66767095; ClinVar: not provided; called by muse, mutect2, varscan2
- RNF213 | c.11819G>A p.R3940H | Missense Mutation (SNP) | VAF 142/544 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs951558125; called by muse, varscan2
- SCNN1D | c.736G>A p.A246T (on ENST00000338555; = p.A410T on NM_001130413.4) | Missense Mutation (SNP) | VAF 110/230 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as rs753657802; called by muse, mutect2, varscan2
- TRPM8 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 156/346 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs199756522; called by muse, mutect2, varscan2
- TULP4 | c.3986G>A p.R1329Q | Missense Mutation (SNP) | VAF 112/295 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.184); catalogued as rs778290647; called by muse, mutect2, varscan2
- WDR33 | c.195G>C p.K65N | Missense Mutation (SNP) | VAF 20/342 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.666); catalogued as rs1459707983; called by muse, mutect2
- BPNT1 | c.584C>G p.T195S | Missense Mutation (SNP) | VAF 166/714 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- BTNL2 | c.293T>G p.I98R | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- CYP4F8 | c.370T>A p.F124I | Missense Mutation (SNP) | VAF 88/317 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- EPS15L1 | c.1316A>G p.E439G | Missense Mutation (SNP) | VAF 138/421 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- GPSM3 | c.326G>A p.S109N | Missense Mutation (SNP) | VAF 117/427 reads (27%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- JRKL | c.1505A>G p.D502G | Missense Mutation (SNP) | VAF 114/267 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MISP | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- MUC16 | c.17247G>T p.M5749I | Missense Mutation (SNP) | VAF 132/218 reads (61%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); called by muse, mutect2
- NUMA1 | c.4540G>C p.G1514R | Missense Mutation (SNP) | VAF 138/288 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- PLPPR3 | c.1874C>T p.A625V (on ENST00000520876 / NM_001270366.2; = p.A653V on NM_024888.2) | Missense Mutation (SNP) | VAF 82/280 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- PRKAA2 | c.22G>T p.D8Y | Missense Mutation (SNP) | VAF 180/426 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- RHEB | c.299A>T p.H100L | Missense Mutation (SNP) | VAF 71/265 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RPL23 | c.341G>A p.G114D | Missense Mutation (SNP) | VAF 83/294 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- TNNT3 | c.292G>A p.E98K (on ENST00000397301 / NM_001367846.1; = p.E87K on NM_006757.4) | Missense Mutation (SNP) | VAF 18/422 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TXLNB | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 90/378 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- YEATS2 | c.2042C>G p.S681C | Missense Mutation (SNP) | VAF 168/459 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ZNF710 | c.1126G>T p.V376F | Missense Mutation (SNP) | VAF 141/211 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- ACOX2 | c.1278G>A p.L426= | Silent (SNP) | VAF 120/282 reads (43%) | called by muse, mutect2, varscan2
- EVC2 | c.2439C>T p.D813= | Silent (SNP) | VAF 117/293 reads (40%) | catalogued as rs370538823; called by muse, mutect2, varscan2
- FAM189B | c.1311C>G p.P437= | Silent (SNP) | VAF 41/406 reads (10%) | called by muse, mutect2, varscan2
- GPR87 | c.615G>A p.T205= | Silent (SNP) | VAF 152/355 reads (43%) | catalogued as rs1485546090; called by muse, mutect2, varscan2
- IRX4 | c.630G>A p.P210= | Silent (SNP) | VAF 205/1081 reads (19%) | catalogued as rs763072295, COSV51471275; called by muse, mutect2, varscan2
- LARS1 | c.1665G>A p.E555= (on ENST00000394434 / NM_020117.11; = p.E528= on NM_016460.3) | Silent (SNP) | VAF 146/572 reads (26%) | called by muse, mutect2, varscan2
- MUC5AC | c.483G>A p.L161= | Silent (SNP) | VAF 180/419 reads (43%) | called by muse, mutect2, varscan2
- PPIH | c.483C>G p.P161= | Silent (SNP) | VAF 16/496 reads (3%) | called by muse, mutect2
- SRGAP1 | c.1239C>A p.S413= | Silent (SNP) | VAF 114/245 reads (47%) | catalogued as COSV61895110; called by mutect2, varscan2
- WNT5A | c.675C>T p.A225= | Silent (SNP) | VAF 107/229 reads (47%) | catalogued as rs371351522, COSV52838149; called by muse, mutect2, varscan2
- CDK7 | c.126+18G>A | Intron (SNP) | VAF 118/842 reads (14%) | called by muse, mutect2, varscan2
- HTR2C | c.-12A>T | 5'UTR (SNP) | VAF 141/152 reads (93%) | called by muse, mutect2, varscan2
- LTBR | c.320-13G>A | Intron (SNP) | VAF 149/294 reads (51%) | catalogued as rs749630743; called by muse, mutect2, varscan2
- MIER2 | chr19:344805 G>T | 5'Flank (SNP) | VAF 59/210 reads (28%) | called by muse, mutect2, varscan2
- NTM | c.-27dup | 5'UTR (INS) | VAF 12/70 reads (17%) | catalogued as rs1408718886; called by mutect2, varscan2
- SLC38A11 | c.520+16C>A | Intron (SNP) | VAF 136/479 reads (28%) | called by muse, mutect2, varscan2
- VGLL3 | c.*93C>G | 3'UTR (SNP) | VAF 56/119 reads (47%) | called by muse, mutect2, varscan2
- YEATS2 | c.3583-9T>C | Intron (SNP) | VAF 63/189 reads (33%) | called by muse, mutect2, varscan2
